Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXT-01A (Primary Tumor).

SPEC #: Status: Obtained: Received:

CLINICAL HISTORY:

ICD-9: 233.1

SPECIMEN/PROCEDURE:

1. CERVIX

IMPRESSION:

CERVICAL BIOPSY:

- . Squamous cell carcinoma with stromal invasion, large cell nonkeratinizing, grade 2.
- . Prominent lymphoplasmacytic infiltrate.

Dictated by:

Entered:

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and cervical biopsy. Received is a pale pink to red tan irregular tissue fragment that is 0.6 x 0.5 x 0.4 cm. The specimen is entirely submitted in cassette #1.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

ICD-0-3
Carcinoma, squamous cell, large
cell, non keratinizing NOS 8072/3
Site: Cervix NOS C53.9
JH 6/13/14

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file dc8c4bd3-1de0-40d4-a68d-cb29b43530ed (TCGA-ZJ-AAXT.963154F2-CBB5-4556-B94D-3E2977CBB3D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).